Gene-level copy-number profile of tumor specimen TCGA-ZB-A969-01A from TCGA case TCGA-ZB-A969, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 72.4 years (26,458 days).
Specimen TCGA-ZB-A969-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.15e283a9-e46e-4390-b6f8-c763c30649d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZB-A969-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10fd6087-2189-4e43-99c0-6c50c7140c4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,591; copy number 2: 54,080; copy number 3: 1,132; copy number 5: 2; copy number 6: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZB-A969-01A-11D-A427-01): tumor purity 0.88, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,892,792–15,118,043, 1 gene (within-gene range 0–1): KAZN.
- chr1:14,221,887–14,777,727, 4 genes: AL357873.1, KAZN-AS1, TBCAP2, AL031293.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:24,886,676–24,902,756, 1 gene, copy number 6: AP000402.1.
- chr21:25,880,550–26,171,128, 1 gene, copy number 6 (within-gene range 3–6): APP.
- chr21:26,158,091–26,217,381, 3 genes, copy number 6 (within-gene range 3–6): AP001439.1, AP000229.1, RNU6-926P.
- chr21:26,835,755–26,845,409, 1 gene, copy number 5: ADAMTS1.
- chr21:40,212,352–40,212,431, 1 gene, copy number 5: MIR4760.

Autosomal genes at a single copy (total copy number 1): 4,591. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
